Somatic mutation profile of tumor specimen TCGA-50-5944-01A (aliquot TCGA-50-5944-01A-11D-1753-08) from TCGA case TCGA-50-5944, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.7 years (25,440 days).
Specimen TCGA-50-5944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6ac0d17-0d1c-4997-8f84-3be523f10618.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5944-10A (Blood Derived Normal), aliquot TCGA-50-5944-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4105ab4-e70d-4c92-98a7-6106a3893516

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Nonsense Mutation 5, 3'UTR 2, Intron 1, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- ACTRT1 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV64418911; called by muse, mutect2, varscan2
- ATRX | c.5219C>A p.S1740* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV64871214, COSV64883603; called by muse, mutect2, varscan2
- BAHCC1 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs530051904, COSV57022691; called by muse, mutect2, varscan2
- CEP95 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs750184995, COSV56747784; called by muse, mutect2, varscan2
- CFL2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV99990552; called by muse, mutect2, varscan2
- COL6A2 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100153885; called by muse, mutect2, varscan2
- CSMD1 | c.2786C>G p.A929G (on ENST00000520002; = p.A928G on NM_033225.6) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59280432; called by muse, mutect2
- CSMD3 | c.4326G>T p.M1442I (on ENST00000297405 / NM_001363185.1; = p.M1338I on NM_052900.3) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV52100079; called by muse, mutect2, varscan2
- DDX39B | c.14A>C p.D5A | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.371); catalogued as COSV58214065; called by muse, mutect2, varscan2
- DPPA4 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.131); catalogued as COSV59509238; called by muse, mutect2, varscan2
- FDFT1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs772157622, COSV99594541; called by muse, mutect2, varscan2
- FGD5 | c.1889C>A p.T630K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53237062; called by muse, mutect2, varscan2
- FRMD8 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs531452921, COSV58211695; called by muse, mutect2, varscan2
- GALNT17 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1471140986, COSV61147266; called by muse, mutect2, varscan2
- GLYATL1 | c.622G>T p.A208S (on ENST00000317391 / NM_001354699.1; = p.A239S on NM_080661.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as rs779789611, COSV100265452; called by muse, mutect2, varscan2
- GYS1 | c.134C>A p.T45K | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54401211; called by muse, mutect2, varscan2
- H3C7 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV99769163; called by muse, mutect2, varscan2
- HEPACAM2 | c.892C>T p.R298C (on ENST00000394468 / NM_001039372.4; = p.R286C on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs868846044, COSV59057692; called by muse, mutect2, varscan2
- IRX6 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51859121, COSV51859694; called by muse, mutect2, varscan2
- ITGAM | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV54941325, COSV99792724; called by muse, mutect2, varscan2
- LRRIQ3 | c.1081T>C p.S361P | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV63040986; called by muse, mutect2, varscan2
- MIA2 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV54481964; called by muse, mutect2, varscan2
- MKLN1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.051); catalogued as rs1427901956, COSV61759934; called by muse, mutect2, varscan2
- MYO1B | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV58426928; called by muse, mutect2, varscan2
- MYRF | c.1106A>G p.Y369C (on ENST00000278836 / NM_001127392.3; = p.Y360C on NM_013279.4) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as rs779346366, COSV53885676; called by muse, mutect2, varscan2
- NAP1L5 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1212893392, COSV99985774; called by muse, mutect2, varscan2
- NCOA1 | c.2227T>G p.S743A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV56038886; called by muse, mutect2, varscan2
- NLRP4 | c.2413C>G p.R805G | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV56707664; called by muse, mutect2, varscan2
- PAK1IP1 | c.419C>A p.S140* | Nonsense Mutation (SNP) | VAF 33/160 reads (21%) | catalogued as COSV65435224; called by muse, mutect2, varscan2
- PCDHGB1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53896610; called by muse, mutect2, varscan2
- PSMC2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53006445; called by muse, mutect2, varscan2
- PTDSS1 | c.1071T>C p.F357= | Splice Region (SNP) | VAF 24/63 reads (38%) | catalogued as COSV61263603; called by muse, mutect2, varscan2
- RGS12 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); catalogued as rs759834164, COSV60674307; called by muse, mutect2, varscan2
- RIOK2 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV51610813; called by muse, mutect2, varscan2
- RSPRY1 | c.1203del p.Y401* | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as COSV68027284; called by mutect2, pindel, varscan2
- SALL1 | c.2219G>A p.G740D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV51753038; called by muse, mutect2, varscan2
- SLC25A12 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55531402; called by muse, mutect2, varscan2
- SLCO1B1 | c.1175T>C p.L392S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV57007073, COSV57015747, COSV57018402; called by muse, mutect2, varscan2
- SPAG4 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 32/262 reads (12%) | catalogued as COSV65329950; called by muse, varscan2
- SPAG4 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV65329958, COSV65330792, COSV65330934; called by muse, mutect2
- SSTR1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942980; called by muse, mutect2, varscan2
- TBC1D16 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs781081023, COSV59988678; called by muse, mutect2, varscan2
- TECRL | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV67085425; called by muse, mutect2, varscan2
- TUBB2B | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV99455534; called by muse, mutect2
- WDFY3 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as COSV55693153; called by muse, mutect2, varscan2
- BTNL2 | c.1296C>T p.D432= | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as rs771592654, COSV66630149; called by muse, mutect2, varscan2
- C5orf51 | c.9C>G p.A3= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV67565442; called by muse, mutect2, varscan2
- CCDC178 | c.2118A>T p.A706= (on ENST00000383096 / NM_001105528.3; = p.A668= on NM_198995.3) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV55758785; called by muse, mutect2, varscan2
- COL17A1 | c.2694C>T p.S898= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV62225164; called by muse, mutect2, varscan2
- ITGAM | c.504G>T p.R168= | Silent (SNP) | VAF 51/191 reads (27%) | catalogued as COSV99792726; called by muse, mutect2, varscan2
- MED13 | c.4872C>A p.I1624= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as COSV67261852; called by muse, mutect2, varscan2
- MMP12 | c.264C>T p.H88= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs201720785, COSV58258994; called by muse, varscan2
- MMP27 | c.1021C>T p.L341= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV52779664; called by muse, varscan2
- OR4D9 | c.675G>A p.L225= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV100259662, COSV100259901; called by muse, mutect2, varscan2
- SIGLEC9 | c.975T>A p.P325= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51582492; called by muse, mutect2
- SYNE1 | c.11886A>G p.Q3962= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV54903449; called by muse, mutect2, varscan2
- TMEM132A | c.474C>T p.P158= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1379848911, COSV50000399; called by muse, mutect2
- TTC14 | c.132C>T p.G44= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1421991206, COSV56009314; called by muse, mutect2, varscan2
- XDH | c.1480C>T p.L494= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs767352182, COSV65146795; called by muse, mutect2, varscan2
- ZZEF1 | c.2307G>A p.Q769= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV67555889; called by muse, varscan2
- BCL2A1 | c.*1C>G | 3'UTR (SNP) | VAF 25/103 reads (24%) | catalogued as COSV99144347; called by muse, mutect2, varscan2
- HDAC9 | c.2577+27C>A | Intron (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- PKD1L2 | n.1072C>A | RNA (SNP) | VAF 45/105 reads (43%) | catalogued as rs1289012202; called by muse, mutect2, varscan2
- XIRP2 | c.*705A>G | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99745089; called by muse, mutect2, varscan2
